Somatic mutation profile of tumor specimen MP2PRT-PAVICX-TMP1-A (aliquot MP2PRT-PAVICX-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVICX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (610 days).
Specimen MP2PRT-PAVICX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a19aca89-12c3-43c9-90ff-9da2341ea737.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVICX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVICX-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70b17bf5-b9db-4637-a55f-0038a82af4d7

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SBNO1 | c.3269G>A p.R1090H (on ENST00000420886; = p.R1089H on NM_018183.5) | Missense Mutation (SNP) | VAF 107/265 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.322); catalogued as rs1302009742; called by muse, mutect2, varscan2
- FBN1 | c.3026C>T p.P1009L | Missense Mutation (SNP) | VAF 202/441 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ANGPTL2 | c.1143C>T p.Y381= | Silent (SNP) | VAF 280/559 reads (50%) | catalogued as rs150529088; called by muse, mutect2, varscan2
- IL6R | c.1134G>A p.T378= | Silent (SNP) | VAF 245/491 reads (50%) | catalogued as rs777288491, COSV59818053; called by muse, mutect2, varscan2
- PRRT2 | c.864C>T p.F288= | Silent (SNP) | VAF 30/548 reads (5%) | catalogued as rs1359563519, COSV54881666; called by muse, mutect2
